Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QW, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QW-01A (Primary Tumor).

Nature of sampling : thymectomy and right upper lobe lung biopsy

Macroscopic examination :

1) Thymus :

Addressed a piece marked with a blue wire on the top right thymic horn , a green wire on the top left thymic horn and a purple wire to the front of thymus . Piece measuring 15 x 8 x 4 cm weighing 115g fresh . Presence of a nodule tumor corporeal left much limited by a thin capsule 4.8 cm . A cutting, tumor is composed of a pink tissue remodeling and having few bleeding . No necrosis. Section slices inked in green.

2) biopsy of the right upper lobe:

A wedge resection of 30 x 10 mm having a small hard nodules of 4 mm in diameter. Limited resection marked by a green ink.

Microscopic examination :

1) Thymus (Blocks A to H):

Histopathological examination revealed a well-circumscribed biphasic tumor capsule, fibrous without refraction.

We find a first tumor epithelial contingent, predominant in certain areas (approximately 20 %) . These areas are comprised of epithelial cells spindle is bundled with rosettes and sometimes in small clumps. cells epithelial show no cytonuclear atypia . They are associated with a lymphocytic contingent with more or less important depending on the area . It consists of small round cells sometimes entangled in the epithelial proliferation . There is no differentiation of bone marrow . No perivascular clear spaces There are a few areas fibrous within the tumor. The tumor is surrounded by a thicker fibrous capsule . Absence of capsular invasion. Complete resection (sliced sections inked in green).

The contingent of spindle epithelial cells is labeled with the antibody anti- cytokeratin KL1 , focally by the anti - CD20 antibodies and negative for anti- CD117 and CD5 . Lymphocyte contingent consists of immature T lymphocytes, CD5 + , CD1a + .

2) right upper lobe lung biopsy :

Presence of a small focus of intrapulmonary osseous metaplasia .

Conclusion :

Thymoma 4.8 cm long axis , sub type AB , completely encapsulated .

Complete surgical resection.

Classification of Masaoka stage I.

ICD-O-3
Thymoma, type AB, malignant 8582/3
Site : Thymus C37.9
Sp 4/2/14

electronic signature

Source: NCI Genomic Data Commons file 2fbcfc63-7446-47b5-b218-d5e830216de6 (TCGA-4V-A9QW.9E96D6A7-3B00-4D13-BAD2-8A71F2866063.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).